MMRF case MMRF_2445 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/56a06787-58e9-4cd4-a027-0c0fabcc0983

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.0 years (23,750 days); ISS stage: I; Days to last known disease status: 613 days (1.7 years); Days to last follow up: 613 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -66: M Protein 1.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.207 mg/dL; Immunoglobulin G 21.6 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.49 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.58 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 5.54 mg/dL.
- Day 39 (ECOG 1): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.891 mg/dL; Immunoglobulin G 8.66 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 400 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 86 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.958 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.543 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 9.3 g/dL; Glucose 8.09 mmol/L.
- Day 144 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.659 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.44 mmol/L.
- Day 263 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.735 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.67 mmol/L.
- Day 333 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.626 mg/dL; Immunoglobulin G 4.28 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 11.3 mmol/L.
- Day 431 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.742 mg/dL; Immunoglobulin G 3.94 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 11.5 mmol/L.
- Day 515 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.823 mg/dL; Immunoglobulin G 6.58 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 5.89 mmol/L.
- Day 613 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.748 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 11.9 mmol/L.

Other clinical attributes
- Day -66: Weight: 117 kg; Height: 243 cm.

Biospecimens (2 samples)
- Sample MMRF_2445_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -66 days.
- Sample MMRF_2445_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -66 days.
